Surgical pathology report (de-identified scan), TCGA case TCGA-DE-A4MA, project TCGA-THCA (Thyroid Carcinoma), tissue source site University of North Carolina, specimen TCGA-DE-A4MA-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY

Case Number :

Diagnosis:

A: "Right submandibular mass", removal

-Lymph node with reactive follicular hyperplasia, negative for malignancy (0/1)

B: Parathyroid, left inferior, removal

-Normocellular parathyroid with no evidence of malignancy

C: Lymph node, prelaryngeal, removal

-Fibrovascular tissue, adipose tissue, and skeletal muscle

-Rare detached lymphocytes, no definite lymph node identified

-No malignancy identified

D: Lymph node, pretracheal, removal

-Fibrovascular tissue, adipose tissue, and skeletal muscle

-No lymph node identified

-No malignancy identified

E: Thyroid gland, total thyroidectomy

Tumor histologic type: Papillary thyroid carcinoma, usual type, with focal oncocytic cytoplasmic features

Tumor size: 4.2 cm, located in the left lobe (gross dimension)

Tumor growth pattern: invasive

100-0-3

Tumor focality: Unifocal

carcinoma, papillary, thyroid 8260/3

Site: thyroid, NOS C73.9

lw
10/2/12

Extent of invasion:

Capsular Invasion: Present, multifocal

Lymphovascular: Present, extensive

Blood vascular: Present

Extra thyroidal extension: Focus suspicious for extra thyroidal involvement of adipose tissue (see comment) (E12)

Surgical margins: Negative but close to black inked posterior (< 1 mm) (E12)

Status of thyroid gland away from tumor: Right thyroid and isthmus negative

Lymph nodes: -7 of 8 left peritracheal lymph nodes positive (see

[page 2 of 4]
part F below)

Size of largest metastasis (greatest dimension): 0.5 cm

Extracapsular (perinodal) extension: Present (F2, F3) (see comment)

Other significant findings: Right thyroid and isthmus negative

AJCC PATHOLOGIC TNM STAGE: pT3 pN 1a pMX

NOTE: This pathologic stage assessment is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

F: Lymph node, left peritracheal, removal
-Seven of eight lymph nodes positive for metastatic papillary thyroid carcinoma, 4 mm in greatest dimension, with involvement of extracapsular adipose tissue (7/8) (See comment)

Comment:

In the thyroidectomy specimen, there is an area of adipose tissue with psammoma bodies identified; however, no malignant epithelial cells are identified in the adipose tissue in this area (E12). Multiple recut sections are examined; however, no definite malignant epithelial cells are identified in the focus. In specimen F (left peritracheal lymph nodes), papillary carcinoma involves adipose tissue. This may be by direct extension (extrathyroidal extension) or extracapsular extension from lymph nodes.

Intraoperative Consult Diagnosis:

An intraoperative consultation was requested in

TPA1/FSA1: Right submandibular lymph node,

- Reactive follicular hyperplasia, no metastatic carcinoma identified

FSB1: "? Left inferior parathyroid"

- Parathyroid tissue present

[page 3 of 4]
Clinical History:

The patient is a -year-old female with likely papillary thyroid carcinoma by FNA and an enlarges submandibular lymph node (benign on FNA).

Gross Description:

Received are six appropriately labeled containers.

Container A is additionally labeled "R submandibular mass" and holds of a 2.9 x 1.4 x 1.6 cm lymph node, sectioned to reveal a tan homogeneous lymphoid parenchyma. Touch prep and representative section submitted as FSA1. Remaining tissue is serially sectioned and submitted as A1-A3.

Container B is additionally labeled "? Left inferior parathyroid" and holds a 0.3 x 0.3 x 0.2 cm red/tan soft tissue fragment totally submitted as FSB,

Container C is additionally labeled "prelaryngeal lymph nodes" and holds a 1.1 x 1 x 1 cm brown/tan fibromuscular soft tissue fragment, trisected and submitted in block C1,

Container D is additionally labeled "pretracheal lymph nodes" and holds a 1.4 x 1.2 x 0.5 cm brown/tan soft tissue fragment, bisected and submitted in D1,

Container E is additionally labeled "thyroid gland, suture on left lobe".

Specimen fixation: Formalin

Type of specimen: Total

Size and weight of specimen: 22.0 grams, overall 6 x 4.5 x 2.5 cm, left lobe 4.5 x 3 x 2.2 cm, right lobe 2.4 x 2.2 x 1.4 cm
Orientation: Anterior/blue, posterior/black, isthmus/yellow

Tumor location: Left lobe

Focality: Unifocal

Dominant tumor: Left, solitary tumor

[page 4 of 4]
Tumor description: Solitary solid well-circumscribed mass with fibrous septae coursing throughout, papillary tan to white.

Tumor size: 4.2 x 3 x 2.2 cm

Confinement/non-confinement: Confined

Distance of tumor to surgical margins: Abuts anterior and posterior margins and is 0.2 cm from the yellow isthmus, 0.3 cm from the inferior pole and abuts the superior pole.

Appearance of thyroid gland away from tumor: brown/tan and homogeneous.

Parathyroids: Not present

Tissue submitted for special investigations: Tumor to tissue procurement

Lymph nodes: Submitted separately

Digital photograph taken: Not taken

Block Summary:

E1-E7 - Entire right lobe, serially sectioned and sequentially submitted from superior to inferior

E8-E9 - Entire isthmus

E10-E21 - Entire left lobe,

Container F is additionally labeled "left peritracheal lymph node" and holds a yellow/tan soft tissue fragment measuring 6.5 x 1.5 x 0.6 cm. One lymph node candidate is identified measuring 0.5 x 0.6 x 0.6 cm.

Block Summary:

F1 - Soft tissue fragment, bisected

F2 - Soft tissue fragment

F3 - One lymph node candidate, bisected,

Diagnostic Discrepancy		X
Histologic Discrepancy		X
Primary Significance History		X
Discrepancy in Primary Notes		X

10/3/12

Source: NCI Genomic Data Commons file 08e51189-371d-4c6a-915f-7b4df609f8f9 (TCGA-DE-A4MA.E9906C93-0069-4908-8547-729F5A015FAC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).